Somatic mutation profile of tumor specimen TCGA-S7-A7WN-01A (aliquot TCGA-S7-A7WN-01A-12D-A35I-08) from TCGA case TCGA-S7-A7WN, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 40.0 years (14,611 days).
Specimen TCGA-S7-A7WN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d93ec704-f1f7-43ef-accd-2a9942149f6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7WN-10A (Blood Derived Normal), aliquot TCGA-S7-A7WN-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfe91f49-5b38-477c-aa75-d319d3ad7c1a

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 37/52 reads (71%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ERCC8 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs565275111; called by muse, mutect2, varscan2
- DGAT1 | c.613T>C p.F205L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ITGA10 | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TP53BP1 | c.4236-1G>C p.X1412_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- HSPA2 | c.222G>A p.L74= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1187065890, COSV99904709; called by muse, mutect2, varscan2
- MYO5B | c.2913G>A p.Q971= | Silent (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- NFKB1 | c.1281T>C p.N427= (on ENST00000394820 / NM_001382627.1; = p.N428= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
